Somatic mutation profile of tumor specimen TCGA-06-6694-01A (aliquot TCGA-06-6694-01A-12D-1845-08) from TCGA case TCGA-06-6694, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.4 years (27,909 days).
Specimen TCGA-06-6694-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc4380fa-db4c-4c49-9de9-dfeacdbea97b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-6694-10A (Blood Derived Normal), aliquot TCGA-06-6694-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6727a27f-b9fd-4c23-848c-23acd50c9724

The open-access MAF lists 102 somatic variants for this specimen: 62 protein-altering or splice-affecting, 36 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 36, Nonsense Mutation 4, Intron 4, Frame Shift Del 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 44/62 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACOT9 | c.584C>A p.P195H | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV60537658; called by muse, mutect2, varscan2
- ADAMDEC1 | c.865A>G p.N289D | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV56475197, COSV99836240; called by muse, mutect2, varscan2
- AKAP14 | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100538264, COSV57630143, COSV57631417; called by muse, mutect2, varscan2
- CDK19 | c.457-1G>A p.X153_splice | Splice Site (SNP) | VAF 36/143 reads (25%) | catalogued as COSV60449299; called by muse, mutect2, varscan2
- CEP97 | c.1265G>T p.R422M | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV59124497; called by muse, mutect2, varscan2
- CHML | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as rs750207699, COSV59363652; called by muse, mutect2, varscan2
- CNGB1 | c.791A>G p.E264G | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.537); catalogued as rs1241802900, COSV51900725; called by muse, mutect2, varscan2
- CTDNEP1 | c.62G>A p.W21* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as rs1567589029, COSV59708679; called by muse, mutect2, varscan2
- CYP3A4 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs372231982, COSV60501882; called by muse, mutect2
- DCAF12L2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.379); catalogued as COSV63580194; called by muse, mutect2, varscan2
- DES | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369765867; called by muse, mutect2, varscan2
- DKK2 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 55/94 reads (59%) | catalogued as COSV53396632; called by muse, mutect2, varscan2
- EPHA10 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV57623946; called by muse, mutect2, varscan2
- EPHB6 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT tolerated (0.48); PolyPhen probably damaging (1); catalogued as rs754050538, COSV67417991; called by muse, mutect2, varscan2
- FAM120A | c.1423A>C p.I475L | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV52904832; called by muse, mutect2, varscan2
- FAM47C | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.914); catalogued as rs373282135, COSV63726468; called by muse, mutect2, varscan2
- FGF7 | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1163604663, COSV51066093; called by muse, mutect2, varscan2
- FLG | c.2303C>T p.A768V | Missense Mutation (SNP) | VAF 111/633 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs764517654, COSV100911755, COSV64241712; called by muse, mutect2, varscan2
- FOXF2 | c.1130A>G p.E377G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV52525763; called by muse, mutect2
- GCNT4 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV59280879, COSV59281465; called by muse, mutect2, varscan2
- HMCN1 | c.12457G>A p.V4153I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.243); catalogued as COSV54899688; called by muse, mutect2, varscan2
- IGKV1D-16 | c.311A>G p.D104G | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1413542085; called by muse, mutect2, varscan2
- IL12B | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs367828574; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IRF9 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV60703187; called by muse, mutect2, varscan2
- JAK2 | c.2309A>T p.H770L | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated (0.72); PolyPhen benign (0.151); catalogued as COSV67610461; called by muse, mutect2, varscan2
- KANK3 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748238931, COSV56846521; called by muse, mutect2, varscan2
- LLGL1 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as rs369006714, COSV100375176; called by muse, mutect2, varscan2
- MACF1 | c.21038G>A p.R7013Q (on ENST00000372915; = p.R5058Q on NM_012090.5) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as rs753741181, COSV57120575; called by muse, mutect2, varscan2
- MAP1A | c.6380C>G p.P2127R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as rs1340057555, COSV100288999, COSV55808638; called by muse, mutect2, varscan2
- MFSD5 | c.97T>A p.C33S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV61565533; called by muse, mutect2
- NUF2 | c.870G>T p.Q290H | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54842659; called by muse, mutect2, varscan2
- OR2A12 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101283208, COSV68821421; called by muse, mutect2
- OR4C11 | c.554T>A p.L185H | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56353151; called by muse, mutect2, varscan2
- OR5AR1 | c.195C>A p.N65K | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV57253768; called by muse, mutect2
- OR5M1 | c.199T>C p.S67P | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV101591559, COSV73202120; called by muse, mutect2, varscan2
- PABPC3 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | catalogued as rs777120288, COSV55800659; called by muse, mutect2, varscan2
- PABPC5 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.304); catalogued as COSV57040711; called by muse, mutect2, varscan2
- PER1 | c.2351C>T p.S784F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57919407; called by mutect2, varscan2
- RFX7 | c.1798C>A p.Q600K (on ENST00000559447 / NM_001368074.1; = p.Q697K on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1243387940, COSV57963281; called by muse, mutect2
- SLC35C1 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs770715892, COSV58479954; called by muse, mutect2, varscan2
- SLC36A2 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs199803602, COSV58862645; called by muse, mutect2, varscan2
- SMC1A | c.854+1G>A p.X285_splice | Splice Site (SNP) | VAF 18/57 reads (32%) | catalogued as COSV59129186; called by muse, mutect2, varscan2
- SPON2 | c.413C>A p.A138E | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV52055059; called by muse, mutect2
- SYN1 | c.334G>C p.A112P | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.298); catalogued as COSV55950274; called by mutect2, varscan2
- SZT2 | c.9202G>A p.G3068S (on ENST00000634258 / NM_001365999.1; = p.G3011S on NM_015284.4) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65094535; called by muse, mutect2, varscan2
- TAFA4 | c.84C>A p.C28* | Nonsense Mutation (SNP) | VAF 28/69 reads (41%) | catalogued as COSV55137619; called by muse, mutect2, varscan2
- TBC1D32 | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234146434, COSV51543111; called by muse, mutect2, varscan2
- TECPR1 | c.2393G>A p.G798E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV65783397; called by muse, mutect2, varscan2
- TEKT5 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 114/327 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs370491307; called by muse, mutect2, varscan2
- TFAP2A | c.227C>T p.S76F (on ENST00000482890; = p.S68F on NM_001032280.3) | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV60233281; called by muse, mutect2, varscan2
- TRAPPC10 | c.3019G>A p.V1007M | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV52377253, COSV52381745; called by muse, mutect2, varscan2
- TUSC3 | c.727A>G p.T243A | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as COSV65881175; called by muse, mutect2, varscan2
- XIRP2 | c.4618C>T p.R1540C (on ENST00000628543; = p.R1715C on NM_152381.6) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs745448561, COSV54699595; called by muse, mutect2, varscan2
- ZBTB7C | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.284); catalogued as rs371251738; called by muse, mutect2, varscan2
- ZFR | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs753860682, COSV54050133; called by muse, mutect2, varscan2
- ZNF449 | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV59347037; called by muse, mutect2, varscan2
- NAA38 | c.95_117del p.E32Afs*32 (on ENST00000575771 / NM_001320925.2; = p.E80Afs*32 on NM_032356.5) | Frame Shift Del (DEL) | VAF 39/78 reads (50%) | called by mutect2, pindel, varscan2
- NOMO2 | c.1061A>G p.Q354R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by mutect2, varscan2
- PTPRZ1 | c.4828del p.H1610Tfs*18 | Frame Shift Del (DEL) | VAF 51/229 reads (22%) | called by mutect2, pindel, varscan2
- TRAK2 | c.183_184del p.F62Sfs*3 | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | called by pindel, varscan2
- VGLL1 | c.439T>A p.S147T | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.173); called by muse, mutect2
- ABCB11 | c.2292G>A p.V764= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as COSV55590361; called by muse, mutect2, varscan2
- ACHE | c.945C>T p.H315= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs775225635, COSV53817462; called by muse, mutect2, varscan2
- ADGRB3 | c.3177A>G p.K1059= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV53244263; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1137T>A p.P379= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV63437884; called by muse, mutect2, varscan2
- BCL2L10 | c.240G>A p.L80= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV53064333; called by muse, mutect2, varscan2
- BMPR1B | c.1455G>C p.L485= | Silent (SNP) | VAF 52/81 reads (64%) | catalogued as COSV52777481; called by muse, mutect2, varscan2
- C19orf18 | c.75G>A p.P25= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs773869458, COSV58705922; called by muse, mutect2, varscan2
- CAMSAP2 | c.3897C>T p.N1299= (on ENST00000236925 / NM_001297707.2; = p.N1288= on NM_203459.3) | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs768512460, COSV52670269; called by muse, mutect2, varscan2
- CARTPT | c.75C>T p.T25= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs748320595, COSV57115006; called by muse, mutect2, varscan2
- CCT8L2 | c.1386C>T p.D462= | Silent (SNP) | VAF 81/183 reads (44%) | catalogued as rs370876356; called by muse, mutect2, varscan2
- CIT | c.4821G>A p.V1607= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV55868380; called by mutect2, varscan2
- CTSS | c.219C>T p.Y73= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs139535421; called by muse, mutect2, varscan2
- DLC1 | c.3450G>A p.L1150= (on ENST00000276297 / NM_001348081.2; = p.L713= on NM_006094.5) | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV52303449; called by muse, mutect2, varscan2
- FAM160A2 | c.1605C>T p.G535= (on ENST00000449352 / NM_001098794.2; = p.G549= on NM_032127.4) | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV56411361; called by muse, mutect2, varscan2
- FBLN7 | c.1050G>A p.T350= | Silent (SNP) | VAF 75/151 reads (50%) | catalogued as rs140504449; called by muse, mutect2, varscan2
- FLNA | c.6297C>T p.D2099= (on ENST00000369850 / NM_001110556.2; = p.D2091= on NM_001456.3) | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs377571943, COSV61042792; called by muse, mutect2, varscan2
- IGF1R | c.522C>T p.P174= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV51272516; called by muse, mutect2, varscan2
- ITGAM | c.933C>T p.H311= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs757822936, COSV54937034; called by muse, mutect2, varscan2
- JPH4 | c.1725G>A p.S575= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs144311601; called by muse, mutect2, varscan2
- JUN | c.351C>T p.A117= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV64664475; called by muse, mutect2, varscan2
- LRP5 | c.3192G>A p.G1064= | Silent (SNP) | VAF 74/92 reads (80%) | catalogued as COSV53715537; called by muse, mutect2, varscan2
- MBTD1 | c.1668A>G p.Q556= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as rs766093480, COSV64503346; called by muse, mutect2, varscan2
- MUC17 | c.12657G>A p.T4219= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as rs200175178; called by muse, mutect2, varscan2
- MYLK2 | c.714C>T p.S238= | Silent (SNP) | VAF 17/179 reads (9%) | catalogued as rs374323310; ClinVar: likely benign; called by muse, mutect2
- MYOF | c.2142C>T p.N714= | Silent (SNP) | VAF 42/55 reads (76%) | catalogued as rs372347097, COSV63704071; called by muse, mutect2, varscan2
- OR4M1 | c.594G>T p.V198= | Silent (SNP) | VAF 48/690 reads (7%) | catalogued as COSV60061291; called by muse, mutect2
- P2RY10 | c.894C>T p.C298= | Silent (SNP) | VAF 158/311 reads (51%) | catalogued as COSV50681271; called by muse, mutect2, varscan2
- RAI2 | c.405C>T p.N135= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as COSV58964192; called by muse, mutect2, varscan2
- RIMBP2 | c.765C>T p.S255= | Silent (SNP) | VAF 53/79 reads (67%) | catalogued as rs774580727, COSV55472145; called by muse, mutect2, varscan2
- RPP25 | c.267G>T p.A89= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV59119961; called by muse, mutect2
- SETD5 | c.1806C>T p.V602= | Silent (SNP) | VAF 67/169 reads (40%) | catalogued as COSV56710892; called by muse, mutect2, varscan2
- SFTPC | c.249C>T p.A83= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as rs751292601, COSV59345497; called by muse, mutect2, varscan2
- TMEM25 | c.573C>T p.T191= | Silent (SNP) | VAF 35/51 reads (69%) | catalogued as rs782759708, COSV57096694; called by muse, mutect2, varscan2
- TNFRSF8 | c.765C>T p.R255= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV55796440; called by muse, mutect2, varscan2
- ZNF169 | c.1542C>T p.Y514= | Silent (SNP) | VAF 33/53 reads (62%) | catalogued as rs200105094; called by muse, mutect2, varscan2
- ZNF302 | c.1032C>G p.A344= (on ENST00000627982; = p.A265= on NM_018443.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV71063545; called by muse, mutect2, varscan2
- CIT | c.2082+1886G>A | Intron (SNP) | VAF 8/127 reads (6%) | catalogued as COSV99949684; called by muse, mutect2
- DYRK1A | c.1671+51G>T | Intron (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100117876, COSV100118009; called by muse, mutect2, varscan2
- NDUFV3 | c.170-4677A>T | Intron (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100447014; called by muse, mutect2, varscan2
- ZNF783 | c.802+3438G>A | Intron (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100954250; called by muse, mutect2, varscan2
